Gene-level copy-number profile of tumor specimen C3N-03222-01 from CPTAC case C3N-03222, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.9 years (26,630 days).
Specimen C3N-03222-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6fae6ca-bb32-4e05-8768-0bae18399d30.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03222-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/7815c0ff-f77f-4618-b669-4393702a34a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 539; copy number 1: 5,933; copy number 2: 28,881; copy number 3: 16,218; copy number 4: 5,163; copy number 5: 1,636; copy number 6: 286; copy number 7: 113; copy number 8: 12; copy number 9: 109.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:5,848,697–5,911,236, 2 genes: AC087369.1, RN7SKP159.
- chr9:21,638,285–23,438,700, 23 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr13:103,420,825–103,444,968, 2 genes: LINC01309, ATP6V1G1P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,156 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,050,441–147,295,734, 31 genes, copy number 5 (within-gene range 2–5): AC239799.2, RNVU1-6, LINC01719, NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15.
- chr1:158,796,014–160,896,076, 86 genes, copy number 5 (broad region; genes not listed).
- chr5:710,355–42,802,439, 599 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:137,227,341–149,028,662, 326 genes, copy number 5 (broad region; genes not listed).
- chr8:12,104,389–12,296,180, 12 genes, copy number 8: ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D.
- chr8:12,570,350–12,581,063, 2 genes, copy number 5: RPS3AP34, AC068587.2.
- chr8:39,451,045–39,522,852, 1 gene, copy number 6: ADAM3A.
- chr8:46,028,804–47,738,164, 35 genes, copy number 6: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD.
- chr8:132,507,962–135,742,495, 54 genes, copy number 6: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr11:54,591,480–58,406,874, 203 genes, copy number 5–7 (broad region; genes not listed).
- chr11:60,813,932–62,426,724, 79 genes, copy number 5–9 (broad region; genes not listed).
- chr11:68,754,620–70,436,584, 51 genes, copy number 7–9: CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:106,310,045–106,311,791, 1 gene, copy number 5: AP002001.2.
- chr11:125,903,247–128,943,399, 53 genes, copy number 7–9: AP000842.2, DDX25, AP000842.1, VSIG10L2, CDON, NAP1L1P1, AP000821.1, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3, KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2, KIRREL3-AS3, AP001993.1, AP003121.1, LINC02712, RN7SKP121, RN7SKP279, AP003532.1, DNAJB6P1, LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1.
- chr14:18,333,726–23,435,660, 392 genes, copy number 5 (broad region; genes not listed).
- chr14:27,612,577–28,830,204, 14 genes, copy number 7 (within-gene range 4–7): LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281.
- chr14:30,370,108–34,539,711, 61 genes, copy number 6 (broad region; genes not listed).
- chr14:35,044,907–38,606,098, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr18:27,225,742–34,226,429, 83 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,952. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
